Somatic mutation profile of tumor specimen TCGA-06-0145-01A (aliquot TCGA-06-0145-01A-01D-1490-08) from TCGA case TCGA-06-0145, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.8 years (19,661 days).
Specimen TCGA-06-0145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3bbe30d-a21b-4fd3-9260-1580124a22e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0145-10A (Blood Derived Normal), aliquot TCGA-06-0145-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d82fdd83-9bbf-4624-80d9-2776b3c46432

The open-access MAF lists 93 somatic variants for this specimen: 69 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Nonsense Mutation 6, Intron 2, RNA 2, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs863223696, CM1512505, COSV61340800, COSV61349273; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.674); catalogued as rs1386171256; called by muse, mutect2, varscan2
- CAMTA1 | c.4066C>T p.R1356W | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs777480195, COSV57916271; called by muse, mutect2, varscan2
- CHEK1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs778046191, COSV54024890; called by muse, mutect2, varscan2
- CNKSR2 | c.2930A>G p.D977G | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs773692431, COSV65279966; called by muse, mutect2, varscan2
- CRIP1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as rs782615467, COSV57635823; called by muse, mutect2, varscan2
- DISP1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV52662554; called by muse, mutect2, varscan2
- DMD | c.6482C>T p.T2161I | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV58933192; called by muse, mutect2
- DOCK8 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs375686155, COSV66633902; called by muse, mutect2, varscan2
- EYA2 | c.1458G>C p.R486S | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57948112, COSV57949476; called by muse, mutect2, varscan2
- FAT2 | c.6350G>A p.R2117Q | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.933); catalogued as rs763727182, COSV55825497; called by muse, mutect2, varscan2
- FOLH1 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 56/170 reads (33%) | catalogued as rs1199329267, COSV57047491; called by muse, mutect2, varscan2
- GABRA1 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV50112403; called by muse, mutect2, varscan2
- GABRE | c.564-2A>T p.X188_splice | Splice Site (SNP) | VAF 29/74 reads (39%) | catalogued as COSV64819707; called by muse, mutect2, varscan2
- GPR143 | c.729del p.I244Sfs*10 | Frame Shift Del (DEL) | VAF 74/228 reads (32%) | catalogued as COSV66632850; called by mutect2, pindel, varscan2
- GRHL3 | c.497C>T p.P166L (on ENST00000350501 / NM_198174.3; = p.P171L on NM_021180.3) | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.702); catalogued as COSV52569372; called by muse, mutect2, varscan2
- GRM1 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1186088869, COSV51215820; called by muse, mutect2, varscan2
- GRM7 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs1255012747, COSV63157550; called by muse, mutect2, varscan2
- HDAC9 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1443545854, COSV101287823, COSV67773704; called by muse, mutect2, varscan2
- HYDIN | c.3688C>A p.Q1230K | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.42); catalogued as COSV66833527; called by muse, mutect2, varscan2
- KEL | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 130/486 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs374644780, COSV62336671; called by muse, mutect2, varscan2
- KIF4A | c.3185A>G p.D1062G | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65544719; called by mutect2, varscan2
- KRT13 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 197/494 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs202015813, COSV55840904, COSV55841784; called by muse, mutect2, varscan2
- LRFN5 | c.846T>A p.F282L | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV53268171; called by muse, mutect2, varscan2
- LUM | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1565758968, COSV57128773; called by muse, mutect2, varscan2
- MCOLN3 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.271); catalogued as rs144793042; called by muse, mutect2, varscan2
- MYCT1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs375330501; called by muse, mutect2, varscan2
- NLRP2 | c.2715G>A p.W905* | Nonsense Mutation (SNP) | VAF 29/150 reads (19%) | catalogued as COSV99672548; called by muse, mutect2, varscan2
- OR51S1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs143553379, COSV59057098; called by muse, mutect2, varscan2
- OR5D18 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV61738076; called by muse, mutect2, varscan2
- P2RY4 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65736964; called by muse, mutect2, varscan2
- PADI3 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs200183399, COSV64934955; called by muse, mutect2, varscan2
- PAN3 | c.1539A>T p.K513N | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56705947; called by muse, mutect2, varscan2
- PAPLN | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as rs773214278, COSV53721374; called by muse, mutect2, varscan2
- PCDHA1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs782203644, COSV65375202; called by muse, mutect2, varscan2
- POM121L12 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.267); catalogued as rs746047304, COSV68692144; called by muse, mutect2, varscan2
- PPFIBP1 | c.2398G>A p.A800T (on ENST00000318304 / NM_177444.3; = p.A794T on NM_003622.4) | Missense Mutation (SNP) | VAF 175/421 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs376329180; called by muse, mutect2, varscan2
- PRKCD | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1317887288, COSV57846377, COSV57846962; called by muse, mutect2, varscan2
- PSG4 | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV54938329; called by muse, mutect2, varscan2
- RGL1 | c.2194A>T p.K732* (on ENST00000360851 / NM_001297672.2; = p.K767* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 56/167 reads (34%) | catalogued as COSV58991031; called by muse, mutect2, varscan2
- RUNX2 | c.1205C>T p.P402L (on ENST00000371438; = p.P380L on NM_001015051.3) | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs770452837, CD104813, COSV100767761, COSV61844036; called by muse, mutect2, varscan2
- RYR2 | c.9352G>A p.G3118R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs730880194, COSV63700997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCML2 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52623764; called by muse, varscan2
- SEMA3C | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746317852; called by muse, mutect2, varscan2
- SLC32A1 | c.1293G>A p.W431* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV54147738; called by muse, mutect2, varscan2
- SLC6A3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165739796, COSV54366298; called by muse, mutect2, varscan2
- SS18 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52262795; called by muse, mutect2, varscan2
- ST6GAL1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 46/156 reads (29%) | PolyPhen probably damaging (0.991); catalogued as rs750933745, COSV51472774; called by muse, mutect2, varscan2
- STARD13 | c.625C>T p.R209C (on ENST00000336934 / NM_001243476.3; = p.R91C on NM_052851.3) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs768133626, COSV55234488; called by muse, mutect2, varscan2
- TAP1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs149070070; called by muse, mutect2
- TEAD4 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 50/107 reads (47%) | catalogued as COSV63281894; called by muse, mutect2, varscan2
- TENM1 | c.3422A>G p.H1141R | Missense Mutation (SNP) | VAF 119/298 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64438406; called by muse, mutect2, varscan2
- TERT | c.1921G>T p.G641* | Nonsense Mutation (SNP) | VAF 54/153 reads (35%) | catalogued as COSV57229156; called by muse, mutect2, varscan2
- THSD7B | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as rs756145411, COSV55681477, COSV99745816; called by muse, mutect2, varscan2
- TJP3 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770316696; called by muse, varscan2
- TKTL2 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180820487, COSV54922318; called by muse, mutect2, varscan2
- TRPA1 | c.2978G>T p.W993L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV51563874, COSV51569055; called by muse, mutect2, varscan2
- UGT2A1 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs767856867, COSV54142254; called by muse, mutect2, varscan2
- XIRP2 | c.3136A>G p.K1046E (on ENST00000628543; = p.K1221E on NM_152381.6) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV54701070; called by muse, mutect2, varscan2
- ZNF521 | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.034); catalogued as COSV64129816; called by muse, mutect2, varscan2
- ZPBP | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs200427468; called by muse, mutect2, varscan2
- ARMT1 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CACNA1C | c.4355C>A p.A1452D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.9781G>A p.E3261K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FRAS1 | c.5563C>A p.H1855N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PIK3C2G | c.3164A>G p.N1055S (on ENST00000676171; = p.N1014S on NM_004570.5) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.5839G>C p.V1947L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF234 | c.1817del p.S606Ifs*63 | Frame Shift Del (DEL) | VAF 47/207 reads (23%) | called by mutect2, pindel, varscan2
- ZNF292 | c.6381A>G p.I2127M | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ALPG | c.984C>T p.F328= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1198288960, COSV54967321; called by muse, mutect2, varscan2
- AMER2 | c.525C>T p.N175= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV63439096; called by muse, mutect2, varscan2
- ATP2B3 | c.171C>T p.S57= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1244211389; called by muse, mutect2, varscan2
- CFAP221 | c.1614C>T p.F538= | Silent (SNP) | VAF 82/216 reads (38%) | catalogued as rs369030643; called by muse, mutect2, varscan2
- CPAMD8 | c.3822C>T p.F1274= (on ENST00000651564; = p.F1227= on NM_015692.5) | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs750599747, COSV71596370, COSV71596814, COSV71597034; called by muse, mutect2, varscan2
- DIAPH2 | c.756A>G p.G252= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV61283305; called by muse, mutect2, varscan2
- EDAR | c.735C>T p.N245= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs370264160; called by muse, mutect2, varscan2
- GRM1 | c.2346C>T p.N782= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as rs145874853; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDC | c.432C>T p.G144= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as rs757801293, COSV51068448; called by muse, mutect2, varscan2
- IRF2 | c.459T>C p.D153= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs767335959; called by muse, mutect2
- JPH2 | c.828C>T p.A276= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV65904774; called by mutect2, varscan2
- MS4A7 | c.117C>T p.N39= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs767560560, COSV55729105; called by muse, mutect2, varscan2
- MYH11 | c.1941G>A p.K647= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV55562913; called by muse, mutect2, varscan2
- NLRP8 | c.288C>T p.R96= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs146471073; called by muse, mutect2, varscan2
- RTL9 | c.720A>G p.E240= | Silent (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- SDS | c.504C>T p.G168= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs185843116; called by muse, mutect2, varscan2
- STAMBPL1 | c.78A>T p.P26= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as COSV64225914; called by muse, mutect2, varscan2
- TSPEAR | c.828G>A p.P276= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs371022077; called by muse, mutect2, varscan2
- UGT1A5 | c.219C>T p.N73= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as COSV59394395; called by muse, mutect2, varscan2
- BIN1 | c.858-1457C>T | Intron (SNP) | VAF 33/97 reads (34%) | catalogued as rs773875712, COSV52120526; called by muse, mutect2, varscan2
- DCHS2 | n.3989C>T | RNA (SNP) | VAF 18/55 reads (33%) | catalogued as COSV61776538; called by muse, mutect2, varscan2
- DNM1P46 | n.561C>T | RNA (SNP) | VAF 7/18 reads (39%) | catalogued as rs753852423; called by muse, mutect2, varscan2
- METTL6 | c.531+231G>C | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580920 A>C | 3'Flank (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
